Surgical pathology report (de-identified scan), TCGA case TCGA-06-1086, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-1086-01A (Primary Tumor).

[page 1 of 4]
Surgical Pathology Report

06-1086

CLINICAL HISTORY

with headaches for [REDACTED] He has a calcified, hyperdense, non-enhancing right frontal mass with a fluid level and vasogenic edema.

OPERATIVE DIAGNOSES

Brain tumor

Operation/Specimen: A: Brain, excision biopsy

B: Brain, excision biopsy

PATHOLOGICAL DIAGNOSIS:

Brain, right cerebral tumor, excision: Gliosarcoma with ependymal differentiation (comment).

COMMENT

The Ki-67 labeling index is up to approximately 75% within the nodules. p53 staining is negative.

The MGMT promoter methylation assay is negative (see below). There is evidence of 1p deletion (see below).

Three cases of gliosarcoma thought to arise in an ependymoma (2 after treatment) have been published. Since osteoid and cartilage can occur in posterior fossa ependymomas, it is possible that this tumor may show some biological overlap with anaplastic ependymoma.

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

[page 2 of 4]
Testing performed on tissue block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of DNA followed by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Interpretation

Findings are suggestive of allelic loss on chromosome arm 1p.

There is no evidence of allelic loss on chromosome arm 19q.

Informative loci are: D1S552, D1S468, D1S1612, D19S412, PLA2G4C, D19S606, D19S1182

Results-Comments

Testing performed on tumor paraffin block [REDACTED] (B1) and peripheral blood for germline comparison.

TEST DESCRIPTION: Allelic loss is assessed by PCR assay in Normal DNA (baseline)/ Tumor DNA pairs using 3 markers at both 1p and 19q. The 3 markers on 1p are D1S548, D1S1592, and D1S552 (with D1S468, D1S1612, and D1S496 as backup markers) and the 3 markers on 19q are D19S219, D19S412, and PLA2G4C (with D19S606 and D19S1182 as backup). All markers are microsatellites (2 or 4 nt repeats) except PLA2G4C which is a minisatellite (26 nt repeat) polymorphism. The markers were selected based on heterozygosity score, amplicon size, and ease of interpretation. The backup markers are used if the first line markers at that chromosome arm are uninformative or otherwise ambiguous in their interpretation. LOH at all informative loci on each chromosomal arm represents the typical finding in oligodendrogliomas with 1p and 19q deletion.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

TECHNICAL SENSITIVITY: The presence of >15% non-neoplastic cells in the sample may preclude the detection of allelic loss.

[page 3 of 4]
[REDACTED]
Proportion of tumor tissue in the submitted tissue curls can not be assessed.

PRINCIPLE: Among the major subtypes of gliomas, oligodendrogliomas are distinguished by their remarkable sensitivity to chemotherapy, with approximately 70% of anaplastic (malignant) oligodendrogliomas responding dramatically to treatment with procarbazine, lomustine, and vincristine (termed PCV) ([REDACTED]). Unfortunately, no clinical or pathologic feature allows accurate prediction of chemotherapeutic response. Oligodendrogliomas are also associated with a longer average patient survival as compared to astrocytic tumors. However, the histologic distinction between oligodendroglioma and astrocytoma is often highly subjective, and there has been significant interobserver variation.

Studies ([REDACTED]) have shown that [REDACTED]

- allelic loss (loss of heterozygosity) of chromosome arm 1p is a statistically significant and currently the best predictor of chemosensitivity
- combined loss involving chromosome arms 1p and 19q predicts both chemotherapeutic response and longer survival in patients with oligodendrogliomas
- combined allelic loss of chromosomes 1p and 19q can be considered a molecular signature of oligodendroglioma (present in approximately 70-80% of oligodendroglial tumors and in only 10% of astrocytomas)

[REDACTED]
=====

INTRA-OPERATIVE CONSULTATION

A.
Brain, excision biopsy, touch prep and smears: Small cell neoplasm with calcification (C/W oligodendroglioma, other...). [REDACTED] Touch preparation smears performed at [REDACTED] and results reported to the Physician of Record.. [REDACTED]

[REDACTED]

GROSS DESCRIPTION

A.
"Right brain tumor", received fresh, one fragment, 0.9 cm. across. Semi-firm, tannish-grey, gritty. In total, A1.

B. Brain, excision biopsy:

SPECIMEN: Right brain tumor

FIXATIVE: none

GENERAL: A tan-pink, rubbery and partially gritty tissue fragment that weighs 3.0 grams and measures 3.5 x 2.0 x 1.2 cm. Sectioning reveals pink-gray cut surfaces.

SECTIONS: All-3

[REDACTED]

MICROSCOPIC DESCRIPTION

[REDACTED]

[page 4 of 4]
Sections show a high-grade glial tumor demonstrating scattered mitotic figures and sheet-like necrosis. Occasional calcifications are noted. There are dense nodules and islands of tumor nuclei and similar nodules of cells with moderate amounts of clear cytoplasm. Looser areas show more spindly cells. Nuclear pleomorphism is mild. Most nuclei are round to oval with fine peppery chromatin. A few nuclei are more angulated, but generally show similar chromatin. Still other areas show almost tanycytic-like cells of clearly ependymal differentiation. A few perivascular pseudorosettes are also present. Focal cartilaginous differentiation and osteoid are also noted. A reticulin stain shows staining around the border of tumor nodules, not individual cells, but shows larger areas of pericellular staining elsewhere. GFAP and pan-keratin stain many of the cells in the nodules and islands, as does NCAM in a relatively strong membranous manner. There is only focal EMA positivity. Vimentin stains both major components of the tumor. Synaptophysin and Melan A are negative.

ICD-9(s):
239.6 239.6

Histo Data

Part A: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
TS H/E x 1		1		
E x 1		1		

Part B: Brain, excision biopsy

Taken:	Received:	Block	Ordered	Comment
Stain/cnt				
CD56-NO x 1		1		
H/E x 1		1		
CK20-DA x 1		1		
CK7-DA x 1		1		
CAM5.2 x 1		1		
MGMT x 1		1		
blood.				Run 1p 19q if you have the
NeuN x 1		1		
Rct 1 H/E x 1		1		
Retic x 1		1		
S100-DA x 1		1		
TTF1-DA x 1		1		
EMA-DA x 1		2		
mGFAP-DA x 1		2		
H/E x 1		2		
KeratinSu x 1		2		
MelanA-DA x 1		2		
MIB1-DA x 1		2		
P53DO7 x 1		2		
Rct 1 H/E x 1		2		
Retic x 1		2		
Synap-DA x 1		2		
Vim-DA x 1		2		
"/E x 1		3		

Source: NCI Genomic Data Commons file 18109f87-c7a1-4163-9c38-b0b2aa202c1c (TCGA-06-1086.D370D57E-200B-49D4-99CF-9C186D7AB947.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).